Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A263, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A263-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Melanoma, malignant, NOS 8720/3

Site: SKIN, back C44.5 per 4/27/11

SPECIMENS:

A. WIDE EXCISION LEFT BACK AND FLANKS

DIAGNOSIS:

A. SKIN, LEFT BACK AND FLANK:

- MALIGNANT MELANOMA, TYPE UNCLASSIFIED, CLARK'S LEVEL V, BRESLOW'S THICKNESS 21 MM. WITH SATELLITE LESIONS.
- SEE TEMPLATE.
- METASTATIC MELANOMA IN TWO SUBCUTANEOUS PERITUMORAL LYMPH NODES (2/2).
- LENTIGINOUS JUNCTIONAL AND COMPOUND NEVI WITH ARCHITECTURAL DISORDER AND MILD TO MODERATE MELANOCYTIC ATYPIA (9 SEPARATE LESIONS).
- ATYPICAL NEVUS PRESENT AT INFERIOR ANTERIOR MARGIN.
- DEEP AND OTHER PERIPHERAL MARGINS ARE NEGATIVE.

Melanoma template

Clark's level: V

Thickness: 21 mm.

Host reaction: Moderate

Mitotic rate: 1-3/10 hpf; Low

Vertical growth: Prominent

Vasc/lymphatic invasion: Absent

Ulceration: Present at the surface of the skin

Regression: Absent

Precursor: Congenital dysplastic nevus

Satellites: present

Predominant cell type: Epithelioid

Surgical margins: Free but within 6 mm of deep margin and atypical nevus present at inferior anterior Margin.

Lymph nodes: Positive (2/2)-peritumoral, subcutaneous

Note: No convincing intraepidermal melanoma is identified in the specimen although multiple dysplastic nevi are present. The growth pattern of diffuse infiltration of dermis and subcutaneous tissue suggest the process may have originated in a congenital nevus. The remainder of peripheral margins will be reported in a supplemental report. Two peri-tumoral lymph nodes are present at subcutaneous tissue with metastatic melanoma.

Pathologist

Electronically signed

ADDENDUM:

The remainder of the peripheral margins have been submitted for review. In the anterior and posterior area margins, two discrete dysplastic nevi with moderate atypia are present.

The rest of the peripheral margins of resection are negative.

Note: Tumor is positive for A103, HMB-45, S-100, tyrosinase and negative for SMA and desmin. This confirms the melanocytic lineage.

SPECIMEN(S):

A. WIDE EXCISION LEFT BACK AND FLANKS

GROSS DESCRIPTION:

A. WIDE EXCISION LEFT BACK AND FLANK:

[page 2 of 2]
Received fresh for tissue procurement and labeled "wide excision" is an ellipse of skin with subcutaneous soft tissue measuring 22x14x6 cm. The skin measures 20x10 cm. There are two stitches attached to the specimen indicating orientation: long stitch-anterior and the short stitch-superior. The specimen is inked as follows: deep-black, anterior-red, superior-yellow, posterior-green, inferior-orange. There is a tumor mass present in the posterior portion with multi-nodular appearance on the surface of skin and extended deeply underneath the skin towards anterior portion, 5.5 cm. in length, 3 cm. in width and 2 cm. in depth, which is 2.5 cm. from closest superior resection margin. The multi-nodular skin portion of mass is 2.3 cm. in length and 2.5 cm. in width. Centrally deep in the subcutaneous tissue shows another mass which is well-circumscribed and convalesced with two more small nodular masses measuring 3x2.6x2.5 cm. in together, which is 0.5 cm. to the closest deep resection margin. It is necrotic centrally with dark pigmentation. Serial section reveals the mass of the skin area is ill defined, deep invading to the subcutaneous tissue with gray-white solid appearance, focally necrotic. The second lesion of subcutaneous is grey-white and fleshy. At the anterior portion of the fatty tissue shows a third, well-circumscribed mass, and 0.4x0.5x0.5 cm with solid and grey white appearance on section. There are also multiple pigmented nevi present in the surface of the skin ranging from 0.2 cm. to 0.7 cm. in greatest dimension. Majority of the pigmented nevi located at the posterior central portion. The rest of the specimen shows multiple fibrotic appearances admixed with fatty and skeletal muscle.

Representative sections are submitted in 29 cassettes:

Summary of the sections:

Cassette 1,2: anterior and posterior tip

Cassettes 3 thru 5: superior anterior, superior medial, superior posterior shave biopsy random

Cassettes 6 thru 8: inferior anterior, inferior mid, inferior posterior shave margin random

Cassette 9,10: mass on the skin

Cassette 11,12: tumor on the skin with adjacent area

Cassette 13,14: the tumor underneath the skin

Cassette 15 : portion of second mass and third mass

Cassette 16 thru 18: second tumor mass with deep margin

Cassette 19 and 20: full thickness of tumor through deep to anterior portion, second mass

Cassette 21: the second mass with the relationship of the anterior skin

Cassette 22: the second mass with deep margin

Cassette 23 thru 25: fibrotic area adjacent to the second tumor mass

Cassette 26 thru 29: sections of the pigmented nevus, 98% submitted

Gross Dictation: ., Pathology Fellow,

Microscopic/Diagnostic Dictation: Pathologist

Final Review:., Pathologist,

Final:., Pathologist,

Addendum:., Pathologist,

Addendum Review:., Pathologist,

Addendum Final:., Pathologist,

Source: NCI Genomic Data Commons file bc1545b2-661a-483b-afb8-0e9282a87f48 (TCGA-GN-A263.817B9EA7-3D5C-433A-AF6D-6701FFBBF8B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).